TCGA case TCGA-08-0355 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bb8230b5-f984-4d28-9f10-b3c89bab1c28

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 30 years; Vital status: Dead; Days to death: 747 days (2.0 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 30.4 years (11,099 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 68 days; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 68 days; Number of cycles: 1; Treatment dose: 75 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 88 days; Days to treatment end: 498 days (1.4 years); Number of cycles: 14; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Initial disease status: Progressive Disease; Days to treatment start: 531 days (1.5 years); Days to treatment end: 531 days (1.5 years); Number of cycles: 1; Treatment dose: 210 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Thalidomide; Initial disease status: Progressive Disease; Days to treatment start: 531 days (1.5 years); Days to treatment end: 572 days (1.6 years); Treatment dose: 1,000 mg/day.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 573 days (1.6 years); Days to treatment end: 607 days (1.7 years); Treatment dose: 540 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 582 days (1.6 years); Days to treatment end: 582 days (1.6 years); Number of cycles: 1; Treatment dose: 590 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Enzastaurin; Initial disease status: Progressive Disease; Days to treatment start: 638 days (1.7 years); Days to treatment end: 671 days (1.8 years).
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 31.8 years (11,618 days); Days to diagnosis: 519 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 615 days (1.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 519 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 519 days (1.4 years).
- Days to follow up: 685 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 747 days (2.0 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Other.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0355-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-08-0355-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-08-0355-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-08-0355-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-08-0355-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Thalomid; Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Temodor.
- Drug treatment 4, Route of administrations: Route of administration: PO.
- Drug treatment 6: Pharmaceutical therapy drug name: Bcnu; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 747 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 747 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 519 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-08-0355-01): tumor purity 0.81, ploidy 1.99, whole-genome doublings 0 (call status: legacy_call).
